Somatic mutation profile of tumor specimen ALCH-B384-TTP1-A (aliquot ALCH-B384-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B384, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.0 years (20,467 days).
Specimen ALCH-B384-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81059e5b-1647-44f7-9d9e-b41ed22dcdf8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B384-NB1-A (Blood Derived Normal), aliquot ALCH-B384-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8787861b-5e49-4b53-b995-86f18114b002

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Nonsense Mutation 1, In Frame Del 1, 5'Flank 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 44/552 reads (8%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 12/220 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- APOB | c.7985C>T p.T2662I | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1191356938; called by muse, mutect2
- CUX2 | c.4280C>A p.A1427D | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.1); catalogued as rs1285489077; called by muse, mutect2
- TERF1 | c.1196G>C p.G399A (on ENST00000276603 / NM_017489.3; = p.G379A on NM_003218.4) | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99400869; called by muse, mutect2, varscan2
- ACTR2 | c.925A>G p.M309V | Missense Mutation (SNP) | VAF 18/403 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CNN2 | c.600del p.M201Wfs*21 | Frame Shift Del (DEL) | VAF 29/306 reads (9%) | called by mutect2, pindel, varscan2
- KIF1A | c.485A>G p.N162S | Missense Mutation (SNP) | VAF 13/340 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.006); called by muse, mutect2
- LHB | c.55T>C p.W19R | Missense Mutation (SNP) | VAF 34/352 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAST2 | c.2605C>G p.P869A | Missense Mutation (SNP) | VAF 18/313 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2
- MSH3 | c.1949C>G p.S650* | Nonsense Mutation (SNP) | VAF 16/134 reads (12%) | called by muse, mutect2, varscan2
- NSD2 | c.2216A>T p.Y739F | Missense Mutation (SNP) | VAF 11/231 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); called by muse, mutect2
- SLC22A12 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 33/318 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SSX5 | c.148T>C p.Y50H (on ENST00000347757 / NM_175723.1; = p.Y91H on NM_021015.4) | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.049); called by muse, mutect2
- TRPS1 | c.1385T>A p.V462E (on ENST00000220888 / NM_001330599.2; = p.V475E on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/536 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); called by muse, mutect2
- VSTM2A | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- PCDHB10 | c.945C>T p.Y315= | Silent (SNP) | VAF 18/296 reads (6%) | called by muse, mutect2
- RBM28 | c.1708C>T p.L570= | Silent (SNP) | VAF 40/808 reads (5%) | called by muse, mutect2
- SIRPG | c.813C>T p.C271= | Silent (SNP) | VAF 24/280 reads (9%) | called by muse, mutect2
- SLC43A3 | c.1437A>G p.E479= | Silent (SNP) | VAF 14/143 reads (10%) | called by muse, mutect2
- TMPRSS6 | c.60G>A p.E20= | Silent (SNP) | VAF 34/423 reads (8%) | catalogued as COSV100696239; called by muse, mutect2
- AP000769.5 | chr11:65499511 A>G | 5'Flank (SNP) | VAF 5/92 reads (5%) | catalogued as rs1480938233; called by muse, mutect2
- NLRP12 | c.2244-259C>T | Intron (SNP) | VAF 4/42 reads (10%) | catalogued as rs1368832297; called by muse, mutect2
